Somatic mutation profile of tumor specimen C3N-02003-01 (aliquot CPT0109740010) from CPTAC case C3N-02003, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 56.8 years (20,728 days).
Specimen C3N-02003-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1862e5c0-47c8-43f0-98a0-5273088ca38f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02003-71 (Blood Derived Normal), aliquot CPT0139170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a592259-b220-4759-af2e-55d6a1a6f0a5

The open-access MAF lists 353 somatic variants for this specimen: 246 protein-altering or splice-affecting, 74 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 219, Silent 74, Nonsense Mutation 17, Intron 17, 3'UTR 5, 5'UTR 5, Splice Region 5, RNA 4, Splice Site 3, 3'Flank 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs137852230, CM940446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5662T>G p.F1888V | Missense Mutation (SNP) | VAF 16/306 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63868094, COSV63868329, COSV63874983; called by muse, mutect2
- TP53 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 77/356 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs864622237, CM137618, COSV52694920, COSV52730114, COSV52730255; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1351T>G p.L451V | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as COSV53966999; called by muse, mutect2, varscan2
- ADAM28 | c.2095C>T p.Q699* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | catalogued as rs779113704; called by muse, mutect2
- ADAMTS12 | c.1482C>T p.N494= | Splice Region (SNP) | VAF 17/228 reads (7%) | catalogued as rs751105630, COSV61272719, COSV61282847; called by muse, mutect2
- AOC3 | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 26/382 reads (7%) | catalogued as COSV53825661, COSV53827494; called by muse, mutect2
- APBB1IP | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66133786; called by muse, mutect2
- BEST3 | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV100437670; called by muse, mutect2
- BTN3A1 | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.828); catalogued as COSV50025073; called by muse, mutect2
- BYSL | c.549A>C p.E183D | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as rs1455812602; called by muse, mutect2
- CCDC158 | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV66355089; called by muse, varscan2
- CDCP2 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV61286066; called by muse, mutect2
- CDH23 | c.2762T>C p.L921P | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1488213305; called by muse, mutect2
- CNTNAP4 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as rs1462893454, COSV100270723; called by muse, mutect2
- CNTNAP4 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs774408296, COSV56663445; called by muse, mutect2
- CREBBP | c.758A>G p.H253R | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as COSV52116376; called by muse, mutect2, varscan2
- CYP21A2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 55/988 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs148622274; called by muse, mutect2
- DST | c.18563G>A p.G6188E (on ENST00000361203 / NM_001374722.1; = p.G3885E on NM_015548.5) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179537914; called by muse, mutect2, varscan2
- DYNC1H1 | c.10859G>A p.R3620K | Missense Mutation (SNP) | VAF 36/515 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); catalogued as COSV64137872; called by muse, mutect2
- ERCC8 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM163462; called by muse, mutect2
- FAM221A | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 19/398 reads (5%) | catalogued as COSV61387341; called by muse, mutect2
- FER1L6 | c.1192T>G p.L398V | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV67551522; called by muse, mutect2
- FLG | c.10450A>C p.S3484R | Missense Mutation (SNP) | VAF 50/538 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64244143; called by muse, mutect2
- FOXD2 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as rs1335922879; called by muse, mutect2
- GALNT12 | c.1027T>C p.S343P | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66663563; called by muse, mutect2, varscan2
- GPATCH8 | c.1374_1377del p.S459Kfs*11 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | catalogued as rs748631863; called by mutect2, pindel, varscan2
- INPP1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs773088923; called by muse, mutect2, varscan2
- KCNJ11 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60594908; called by muse, mutect2
- KIF22 | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99361465; called by muse, mutect2
- KIFC3 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); catalogued as COSV65551003; called by muse, mutect2
- KLHL33 | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 31/428 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as COSV60727223; called by muse, mutect2
- LGALS2 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 32/568 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs759280899, COSV50760276; called by muse, mutect2
- LLGL2 | c.694-1G>A p.X232_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | catalogued as COSV51341751; called by muse, mutect2
- MAGEB17 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 13/132 reads (10%) | catalogued as COSV61556936; called by muse, mutect2, varscan2
- MRPL24 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs996693419; called by muse, mutect2
- MRPS18B | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs753507164; called by muse, mutect2, varscan2
- MUC16 | c.4414A>C p.T1472P | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV101199311; called by muse, mutect2
- MYH1 | c.3206C>T p.S1069F | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV56843664, COSV99875065; called by muse, mutect2
- MZF1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV53043536; called by muse, mutect2, varscan2
- NID2 | c.1146A>C p.Q382H | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs772105671; called by muse, mutect2, varscan2
- NLRP4 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as COSV56716955; called by muse, mutect2
- OLR1 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV58872828; called by muse, mutect2
- OR13G1 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62944972; called by muse, mutect2
- OR1A2 | c.527A>C p.N176T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67936962; called by muse, mutect2, varscan2
- OR4M1 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 30/489 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV60063573; called by muse, mutect2
- OR6C76 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.684); catalogued as rs545625846; called by muse, mutect2, varscan2
- OR6N1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as rs1488715776, COSV58649215; called by muse, mutect2
- PAX4 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 52/422 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.144); catalogued as rs1167019451; called by muse, mutect2, varscan2
- PCDHB6 | c.1736A>G p.E579G | Missense Mutation (SNP) | VAF 38/714 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs782481190; called by muse, mutect2
- PIEZO2 | c.6039A>C p.E2013D | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99555168; called by muse, mutect2
- PLA2G3 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as COSV53209282; called by muse, mutect2
- PRG4 | c.2450A>G p.K817R | Missense Mutation (SNP) | VAF 30/445 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV63355807; called by muse, mutect2
- RAI1 | c.3082G>C p.E1028Q | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.867); catalogued as COSV55396936; called by muse, mutect2
- RCN3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1451801927, COSV54541357; called by muse, mutect2
- RRNAD1 | c.1399C>G p.L467V | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as rs374747953, COSV63929346; called by muse, mutect2
- SLC9A3R1 | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1003334664; called by muse, mutect2
- SPAG17 | c.4719G>A p.M1573I | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs749203278, COSV60466350; called by muse, mutect2
- SPHKAP | c.4885C>T p.Q1629* (on ENST00000392056 / NM_001142644.2; = p.Q1600* on NM_030623.3) | Nonsense Mutation (SNP) | VAF 24/276 reads (9%) | catalogued as COSV100764637; called by muse, mutect2
- SPTB | c.6307C>T p.P2103S | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1330172047; called by muse, mutect2
- TAOK2 | c.614A>C p.K205T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54233424; called by mutect2, varscan2
- TARS1 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs756937101, COSV54309238; called by muse, mutect2
- TOGARAM1 | c.3143A>G p.D1048G | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as rs763560311, COSV63890474; called by muse, mutect2, varscan2
- TSHR | c.2015G>T p.C672F | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM941337; called by muse, mutect2, varscan2
- TTC37 | c.3100G>A p.G1034S | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1561336716; called by muse, mutect2
- TTN | c.43087G>C p.E14363Q (on ENST00000591111; = p.E6939Q on NM_003319.4) | Missense Mutation (SNP) | VAF 28/364 reads (8%) | PolyPhen benign (0.346); catalogued as rs1305953554; called by muse, mutect2
- UNC5A | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56167000; called by muse, mutect2, varscan2
- UQCRFS1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV59184980, COSV59184989; called by muse, mutect2
- USH2A | c.4826A>G p.E1609G | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV100233422, COSV56368435; called by muse, mutect2
- VTCN1 | c.552A>C p.Q184H | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.738); catalogued as COSV60223389; called by muse, mutect2
- ZFPM1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); catalogued as rs1399684151; called by muse, mutect2, varscan2
- ZHX2 | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747503368; called by muse, mutect2, varscan2
- ZNF534 | c.654A>C p.Q218H (on ENST00000332323 / NM_001143939.3; = p.Q205H on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV56517240, COSV99990144; called by muse, mutect2
- ZNF689 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs750466705; called by muse, mutect2, varscan2
- ZP4 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs911377229; called by muse, mutect2, varscan2
- ACACA | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 23/338 reads (7%) | called by muse, mutect2
- ACADS | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 41/534 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2
- ACOT12 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ADAMTS7 | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- ADGRF5 | c.3644T>G p.F1215C | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRF5 | c.2339T>C p.L780P | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- AGAP3 | c.2009A>C p.H670P (on ENST00000622464; = p.H706P on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- AHNAK | c.12470A>C p.D4157A | Missense Mutation (SNP) | VAF 36/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ALG12 | c.519C>G p.I173M | Missense Mutation (SNP) | VAF 12/292 reads (4%) | PolyPhen probably damaging (0.928); called by muse, mutect2
- ANAPC2 | c.1085A>C p.K362T | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANGEL1 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGAP30 | c.2106A>C p.K702N | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2
- ARHGAP32 | c.4912C>T p.Q1638* (on ENST00000310343 / NM_001378025.1; = p.Q1289* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 20/502 reads (4%) | called by muse, mutect2
- ARHGAP45 | c.1696A>G p.N566D | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ARHGAP45 | c.1697A>T p.N566I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF28 | c.231A>C p.E77D | Missense Mutation (SNP) | VAF 21/407 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- B3GNT3 | c.576C>G p.F192L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); called by muse, mutect2
- CCL15 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CD3D | c.413A>C p.D138A | Missense Mutation (SNP) | VAF 94/861 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CECR2 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CENPQ | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- CEP192 | c.5314C>G p.L1772V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.269); called by muse, mutect2
- CEP70 | c.832A>T p.S278C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP43 | c.4732T>G p.F1578V | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CFAP65 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CILP | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.319); called by muse, mutect2
- CKAP5 | c.5357A>C p.N1786T (on ENST00000529230 / NM_001008938.4; = p.N1726T on NM_014756.3) | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.259); called by muse, mutect2
- CLCN2 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 20/421 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2
- CNTD1 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2
- COG8 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 36/398 reads (9%) | called by muse, mutect2
- COL4A1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL7A1 | c.7763A>G p.Q2588R | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CRACR2B | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- CRYBA1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 29/600 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); called by muse, mutect2
- CSF2RA | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.138); called by muse, mutect2
- CYP3A4 | c.1347-1G>T p.X449_splice (on ENST00000336411; = p.X418_splice on NM_017460.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- DCAF10 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); called by muse, varscan2
- DCHS1 | c.999A>C p.Q333H | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDC | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DEFB121 | c.127T>G p.L43V | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- DENND2A | c.2288T>G p.L763R | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DISP1 | c.4541T>G p.L1514R | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); called by muse, mutect2
- DNAH14 | c.6553T>G p.L2185V (on ENST00000445597; = p.L2838V on NM_001367479.1) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNAH17 | c.7456T>G p.F2486V | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB11 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DNAJC6 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- DPYD | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- DYTN | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EFCAB5 | c.1444A>G p.S482G | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2
- ERN2 | c.1732T>G p.F578V | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- F12 | c.883T>C p.C295R | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM47C | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FASN | c.5224G>C p.D1742H | Missense Mutation (SNP) | VAF 33/694 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- FBXO5 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2
- FRY | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- FYB2 | c.1739A>C p.K580T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2
- FZD3 | c.757T>G p.F253V | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.401); called by muse, mutect2
- GBA2 | c.2197+4A>C | Splice Region (SNP) | VAF 72/409 reads (18%) | called by muse, mutect2, varscan2
- GLT8D2 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); called by muse, mutect2
- GTF2H4 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- HAO2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- HBP1 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HELQ | c.3137T>C p.L1046P | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HK3 | c.2376C>G p.F792L | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- HNRNPD | c.109dup p.A37Gfs*33 | Frame Shift Ins (INS) | VAF 28/255 reads (11%) | called by mutect2, pindel, varscan2
- HTR2A | c.421T>A p.W141R | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ICAM2 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IGLON5 | c.418T>C p.S140P | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); called by muse, mutect2
- JADE2 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- KAT5 | c.1035C>A p.D345E | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KAT6A | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2
- KCNMA1 | c.1439A>C p.K480T | Missense Mutation (SNP) | VAF 35/389 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDM1A | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- KDM2A | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, varscan2
- KIAA0586 | c.3667G>A p.E1223K (on ENST00000619416 / NM_001244190.2; = p.E1162K on NM_014749.5) | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIAA1109 | c.6755A>C p.K2252T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KIAA1210 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- KIAA1549L | c.3143A>C p.N1048T (on ENST00000321505; = p.N1345T on NM_012194.3) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- KLK5 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 24/387 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- KPNA3 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.114); called by muse, mutect2
- KSR1 | c.1640C>G p.S547* (on ENST00000644974 / NM_001367810.1; = p.S432* on NM_014238.2) | Nonsense Mutation (SNP) | VAF 28/424 reads (7%) | called by muse, mutect2
- L3MBTL1 | c.611T>G p.L204R (on ENST00000418998 / NM_001377303.1; = p.L114R on NM_015478.7) | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- LAMC2 | c.2053A>T p.R685W | Missense Mutation (SNP) | VAF 63/336 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- LCOR | c.3195A>C p.Q1065H | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.132); called by muse, mutect2
- LIFR | c.822A>C p.Q274H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2
- MAP3K11 | c.2353G>A p.G785R | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARF1 | c.1139A>C p.K380T | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.301); called by muse, mutect2
- MATN2 | c.835A>C p.I279L | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2
- MCM10 | c.1579A>C p.T527P (on ENST00000484800 / NM_182751.3; = p.T526P on NM_018518.5) | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MCM3 | c.219G>A p.T73= (on ENST00000229854 / NM_001366374.2; = p.E26K on NM_002388.6 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 41/358 reads (11%) | called by muse, mutect2, varscan2
- MDC1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MEIOC | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.122); called by muse, mutect2
- METTL3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MTMR4 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- MTRF1 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTSS2 | c.2171T>C p.L724P | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO18B | c.5463G>A p.M1821I | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- MYO1A | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 40/606 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- NAV3 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEB | c.3677A>C p.K1226T | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- NFE2 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 15/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- NFKBIE | c.808G>C p.E270Q (on ENST00000275015; = p.E131Q on NM_004556.3) | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.374); called by muse, mutect2
- NME9 | c.128A>T p.K43I (on ENST00000333911 / NM_001349024.2; = p.K21I on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NOXA1 | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN1 | c.2825T>C p.I942T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NTN5 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.009); called by muse, mutect2
- NYAP1 | c.1676A>C p.K559T | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- OR2AT4 | c.265T>G p.L89V | Missense Mutation (SNP) | VAF 27/495 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.851); called by muse, mutect2
- OR2T35 | c.518A>C p.E173A | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2
- PCDHA9 | c.1754T>C p.V585A | Missense Mutation (SNP) | VAF 52/449 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCDHAC1 | c.1004A>C p.D335A | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHB3 | c.1198T>C p.F400L | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- PCF11 | c.4141C>G p.H1381D | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PCSK7 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 171/460 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PDE8A | c.1937T>G p.F646C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGBD5 | c.1160A>C p.D387A (on ENST00000525115; = p.D456A on NM_001258311.2) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKG1 | c.317+4A>C | Splice Region (SNP) | VAF 36/231 reads (16%) | called by muse, mutect2, varscan2
- PHLDB1 | c.3299A>G p.E1100G | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2
- PI4KB | c.2309G>A p.R770Q (on ENST00000368873 / NM_001369623.1; = p.R782Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.034); called by muse, mutect2
- PIGQ | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PIK3C2A | c.4132A>C p.S1378R | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PJA2 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2
- PLK4 | c.2707A>C p.T903P | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.376); called by muse, mutect2
- POLR2B | c.2975A>C p.N992T | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2
- PPFIA1 | c.1446A>C p.E482D | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PPP4R3C | c.1289A>C p.E430A | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PRKRA | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.435); called by muse, mutect2
- R3HDML | c.746A>C p.K249T | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, mutect2
- RAD51AP1 | c.15G>A p.V5= | Splice Region (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- RBM39 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ROR2 | c.1203G>C p.K401N | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.164); called by muse, mutect2
- RPRD2 | c.2773T>A p.S925T | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- RPS3 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 97/257 reads (38%) | called by muse, mutect2, varscan2
- RRAGD | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2
- SCN9A | c.2639T>C p.F880S (on ENST00000303354; = p.F869S on NM_002977.3) | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC13 | c.485T>G p.V162G (on ENST00000350697 / NM_183352.3; = p.V165G on NM_030673.4) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SEMA3G | c.2132T>C p.L711P | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SEPTIN3 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.22); called by muse, mutect2
- SERPINA10 | c.1266C>G p.F422L | Missense Mutation (SNP) | VAF 19/361 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIM1 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SLC36A1 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SLC8A3 | c.805A>T p.K269* | Nonsense Mutation (SNP) | VAF 55/410 reads (13%) | called by muse, mutect2, varscan2
- SMIM30 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- SNTG2 | c.1099T>C p.W367R | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2
- SPTA1 | c.5777A>G p.D1926G | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- SWAP70 | c.1712T>G p.L571R | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TCERG1 | c.1557G>C p.Q519H | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- TET2 | c.1905A>C p.Q635H | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- TFR2 | c.1271-1G>A p.X424_splice | Splice Site (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- TIMELESS | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.099); called by muse, mutect2
- TLR3 | c.1165T>C p.S389P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- TLR9 | c.542A>T p.K181M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2
- TM6SF1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.471); called by muse, mutect2
- TMIGD2 | c.796A>C p.S266R | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNNI1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TRRAP | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- TSC22D1 | c.2677A>C p.S893R | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); called by muse, mutect2
- UBE3B | c.2093T>C p.L698P | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UBR4 | c.14375A>C p.K4792T | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- UNC93B1 | c.1639T>G p.S547A | Missense Mutation (SNP) | VAF 158/470 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, varscan2
- USP17L7 | c.987T>G p.S329R | Missense Mutation (SNP) | VAF 48/1196 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.124); called by muse, mutect2
- VWA3A | c.2510A>C p.K837T | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- WDR93 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- WFDC8 | c.347A>T p.K116I | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2
- ZC3H15 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZFHX4 | c.376A>T p.N126Y | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF761 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2
- ZNF786 | c.1568A>C p.K523T | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2
- ZSWIM3 | c.1775T>C p.L592P | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.116); called by muse, mutect2
- ZSWIM7 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ZXDA | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- AHR | c.2196T>G p.T732= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- ANKRD12 | c.5928T>C p.S1976= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs772307993; called by muse, mutect2, varscan2
- APOD | c.186C>T p.I62= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- ARMH4 | c.2181C>T p.F727= | Silent (SNP) | VAF 11/276 reads (4%) | catalogued as rs1216758163, COSV99957540; called by muse, mutect2
- ARNT | c.1914T>G p.T638= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- ATP11A | c.555A>G p.G185= | Silent (SNP) | VAF 35/301 reads (12%) | catalogued as rs750572978; called by muse, mutect2, varscan2
- BEND3 | c.1257C>T p.F419= | Silent (SNP) | VAF 7/172 reads (4%) | catalogued as COSV100944567; called by muse, mutect2
- BMPER | c.75C>T p.V25= | Silent (SNP) | VAF 46/510 reads (9%) | called by muse, mutect2
- CABIN1 | c.1326A>G p.E442= | Silent (SNP) | VAF 15/374 reads (4%) | called by muse, mutect2
- CACNB1 | c.210T>C p.S70= | Silent (SNP) | VAF 43/245 reads (18%) | catalogued as rs1255630796; called by muse, mutect2, varscan2
- CCDC62 | c.606G>A p.V202= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- CSMD2 | c.3495A>G p.G1165= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- CYP2B6 | c.312C>T p.V104= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs1348111588; called by muse, mutect2
- DCAF10 | c.1356T>G p.P452= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2
- DENND2B | c.1983C>T p.F661= | Silent (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- EIF4G2 | c.129A>T p.P43= | Silent (SNP) | VAF 49/330 reads (15%) | called by muse, mutect2, varscan2
- FAF1 | c.1623G>A p.Q541= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- FAM161B | c.417G>A p.Q139= (on ENST00000651776; = p.Q76= on NM_152445.3) | Silent (SNP) | VAF 20/365 reads (5%) | called by muse, mutect2
- FAT4 | c.4977T>C p.S1659= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- FLNB | c.1638A>G p.E546= | Silent (SNP) | VAF 83/508 reads (16%) | called by muse, mutect2, varscan2
- FURIN | c.1710C>G p.L570= | Silent (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- G6PD | c.363C>T p.L121= | Silent (SNP) | VAF 29/255 reads (11%) | called by muse, mutect2, varscan2
- GCNT1 | c.1254G>A p.L418= | Silent (SNP) | VAF 14/173 reads (8%) | catalogued as rs1427613963; called by muse, mutect2
- GFM2 | c.15G>A p.L5= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- GJB5 | c.87C>T p.F29= | Silent (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- GRIK1 | c.498C>T p.L166= | Silent (SNP) | VAF 19/219 reads (9%) | called by muse, mutect2
- HTT | c.21G>A p.L7= | Silent (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- IGLV3-19 | c.240C>T p.F80= | Silent (SNP) | VAF 15/284 reads (5%) | called by muse, mutect2
- IL17F | c.474C>G p.V158= | Silent (SNP) | VAF 34/442 reads (8%) | called by muse, mutect2
- IMMP2L | c.264G>A p.K88= | Silent (SNP) | VAF 4/41 reads (10%) | called by mutect2, varscan2
- KAT6B | c.114T>G p.T38= | Silent (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
- KCNA4 | c.1230C>T p.V410= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV100069354; called by muse, mutect2, varscan2
- KCNMB1 | c.354C>T p.A118= | Silent (SNP) | VAF 28/235 reads (12%) | catalogued as rs761058886; called by muse, mutect2
- LHCGR | c.1056C>G p.P352= | Silent (SNP) | VAF 12/199 reads (6%) | called by muse, mutect2
- MFSD9 | c.1293G>A p.G431= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- MGAT5 | c.1296G>A p.L432= | Silent (SNP) | VAF 12/94 reads (13%) | called by mutect2, varscan2
- MRPS23 | c.75G>C p.L25= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- MUC4 | c.6210T>G p.P2070= | Silent (SNP) | VAF 20/408 reads (5%) | called by muse, mutect2
- MYBPC3 | c.1002G>A p.E334= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV57030471; called by muse, mutect2, varscan2
- MYCBP2 | c.5760A>G p.P1920= (on ENST00000357337; = p.P1958= on NM_015057.5) | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as rs1172034753; called by muse, mutect2, varscan2
- MYT1 | c.1539T>C p.A513= | Silent (SNP) | VAF 20/247 reads (8%) | called by muse, mutect2
- NLRP10 | c.1633C>T p.L545= | Silent (SNP) | VAF 9/193 reads (5%) | called by muse, mutect2
- NOP14 | c.75G>A p.A25= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as rs1317966734; called by muse, mutect2
- NOTCH4 | c.2094A>G p.A698= | Silent (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- NRM | c.36C>T p.L12= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as COSV99223596; called by muse, mutect2
- NT5C | c.489C>T p.F163= | Silent (SNP) | VAF 17/268 reads (6%) | called by muse, mutect2
- PBRM1 | c.429G>A p.L143= | Silent (SNP) | VAF 12/181 reads (7%) | catalogued as rs1401786866; called by muse, mutect2
- PCBP4 | c.186C>T p.I62= | Silent (SNP) | VAF 23/477 reads (5%) | called by muse, mutect2
- PCDHB7 | c.1893C>T p.S631= | Silent (SNP) | VAF 47/994 reads (5%) | catalogued as rs781839893, COSV50762936; called by muse, mutect2
- PCMTD2 | c.78T>G p.T26= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- PIGR | c.1173G>A p.Q391= | Silent (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- PLEC | c.5148G>A p.Q1716= (on ENST00000322810 / NM_201380.4; = p.Q1606= on NM_000445.5) | Silent (SNP) | VAF 26/382 reads (7%) | called by muse, mutect2
- PPARGC1B | c.1752T>G p.T584= | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- RBM4B | c.714T>G p.A238= | Silent (SNP) | VAF 33/340 reads (10%) | called by muse, mutect2
- RXRG | c.423C>T p.I141= | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- RYR1 | c.2397C>T p.F799= | Silent (SNP) | VAF 44/520 reads (8%) | called by muse, mutect2
- SEC13 | c.723C>T p.F241= (on ENST00000350697 / NM_183352.3; = p.F244= on NM_030673.4) | Silent (SNP) | VAF 18/205 reads (9%) | called by muse, mutect2
- SEC24A | c.2052A>G p.Q684= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- SHROOM3 | c.4407T>C p.T1469= | Silent (SNP) | VAF 22/390 reads (6%) | called by muse, mutect2
- SLC26A11 | c.180C>T p.L60= | Silent (SNP) | VAF 16/279 reads (6%) | called by muse, mutect2
- SSC5D | c.4371C>G p.L1457= | Silent (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- STARD3 | c.900G>C p.V300= | Silent (SNP) | VAF 20/364 reads (5%) | called by muse, mutect2
- TBX5 | c.1188C>T p.I396= | Silent (SNP) | VAF 45/522 reads (9%) | catalogued as COSV59862086; called by muse, mutect2
- TDRD15 | c.2152T>C p.L718= | Silent (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- TIMP2 | c.237C>T p.F79= | Silent (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- TMEM79 | c.930C>T p.L310= | Silent (SNP) | VAF 32/326 reads (10%) | called by muse, mutect2, varscan2
- TRIM6 | c.1173T>G p.A391= | Silent (SNP) | VAF 26/404 reads (6%) | catalogued as COSV53475723; called by muse, mutect2
- TRPM5 | c.2556C>T p.I852= | Silent (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- UGT1A4 | c.432T>G p.T144= | Silent (SNP) | VAF 22/303 reads (7%) | called by muse, mutect2
- USF3 | c.3852T>C p.S1284= | Silent (SNP) | VAF 13/229 reads (6%) | called by muse, mutect2
- WHAMM | c.1050C>T p.L350= | Silent (SNP) | VAF 10/163 reads (6%) | called by muse, mutect2
- ZNF536 | c.849C>T p.F283= | Silent (SNP) | VAF 10/211 reads (5%) | catalogued as COSV62833513; called by muse, mutect2
- ZNF652 | c.1434C>T p.F478= | Silent (SNP) | VAF 24/440 reads (5%) | called by muse, mutect2
- ZSWIM1 | c.990C>G p.L330= | Silent (SNP) | VAF 33/333 reads (10%) | called by muse, mutect2, varscan2
- ACTA1 | c.*37A>C | 3'UTR (SNP) | VAF 15/298 reads (5%) | catalogued as rs1433448236; called by muse, mutect2
- AGBL3 | c.311-6984C>A | Intron (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851088 T>C | 3'Flank (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- ANAPC11 | c.110-487C>G | Intron (SNP) | VAF 25/485 reads (5%) | called by muse, mutect2
- BCL3 | c.1060-47G>A | Intron (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- CFL2 | c.*382C>T | 3'UTR (SNP) | VAF 21/333 reads (6%) | catalogued as rs1413025049; called by muse, mutect2
- CMC2 | c.153+994A>C | Intron (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- COL9A2 | c.363+30C>T | Intron (SNP) | VAF 32/412 reads (8%) | catalogued as rs757633582; called by muse, mutect2
- DAAM2 | c.258+38C>G | Intron (SNP) | VAF 27/471 reads (6%) | called by muse, mutect2
- DENND1C | c.679-10C>T | Intron (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- DUSP13 | c.*325A>G | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- DZANK1 | chr20:18381266 C>T | 3'Flank (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- FAM90A20P | n.290A>C | RNA (SNP) | VAF 24/531 reads (5%) | called by muse, mutect2
- FGFR3 | c.*867del | 3'UTR (DEL) | VAF 11/90 reads (12%) | catalogued as COSV53401260; called by mutect2, pindel, varscan2
- GALNT14 | c.129+23151C>T | Intron (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- GIMAP6 | c.86-76G>C | Intron (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- HAS2-AS1 | n.769A>T | RNA (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- HLA-DMA | c.*66C>T | 3'UTR (SNP) | VAF 26/348 reads (7%) | called by muse, mutect2
- ITK | c.-28A>C | 5'UTR (SNP) | VAF 15/212 reads (7%) | called by muse, mutect2
- LACTB2 | c.286+1021G>A | Intron (SNP) | VAF 38/538 reads (7%) | called by muse, mutect2
- LILRB1 | c.1800+150T>G | Intron (SNP) | VAF 40/488 reads (8%) | called by muse, mutect2
- LINC00955 | n.361T>G | RNA (SNP) | VAF 32/289 reads (11%) | called by muse, mutect2
- PLD3 | c.-10T>G | 5'UTR (SNP) | VAF 31/210 reads (15%) | called by muse, mutect2, varscan2
- POLG2 | c.-3G>C | 5'UTR (SNP) | VAF 30/544 reads (6%) | catalogued as rs1555669683; called by muse, mutect2
- PTENP1 | n.1765T>C | RNA (SNP) | VAF 51/240 reads (21%) | called by muse, mutect2, varscan2
- RPRML | c.-1G>A | 5'UTR (SNP) | VAF 11/101 reads (11%) | catalogued as rs1330649554; called by muse, mutect2, varscan2
- SERINC5 | c.1239-2678T>G | Intron (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
- SIRT7 | c.408-11C>T | Intron (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- SORBS2 | c.685-7526T>C | Intron (SNP) | VAF 18/170 reads (11%) | catalogued as COSV99509840; called by muse, mutect2, varscan2
- STAT3 | c.1748+13G>C | Intron (SNP) | VAF 44/840 reads (5%) | called by muse, mutect2
- TAFA4 | c.-7A>G | 5'UTR (SNP) | VAF 13/90 reads (14%) | catalogued as rs755447126; called by muse, mutect2, varscan2
- TMEM123 | c.157+529A>C | Intron (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- UMODL1 | c.603+1195C>G | Intron (SNP) | VAF 31/283 reads (11%) | called by muse, mutect2, varscan2
